Somatic mutation profile of tumor specimen TCGA-FB-AAPQ-01A (aliquot TCGA-FB-AAPQ-01A-11D-A40W-08) from TCGA case TCGA-FB-AAPQ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-FB-AAPQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bc15d2b-f706-4576-be77-100415d2d103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPQ-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPQ-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b886b10-30d7-4023-98dd-5547639a453f

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 3, Frame Shift Del 3, Translation Start Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 51/215 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 62/208 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKK1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746405597, COSV58273266, COSV58274845; called by muse, mutect2, varscan2
- BMP7 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 118/437 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67780356; called by muse, mutect2, varscan2
- CCDC69 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV100815263; called by muse, mutect2, varscan2
- CHML | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 18/453 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100087944; called by muse, mutect2
- CPB1 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs866048233, COSV99294583; called by muse, mutect2, varscan2
- CYP2R1 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 12/274 reads (4%) | catalogued as COSV100585017; called by muse, mutect2
- DOCK3 | c.5638G>A p.G1880S | Missense Mutation (SNP) | VAF 135/464 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.998); catalogued as rs749925387, COSV56501857; called by muse, mutect2, varscan2
- ELK1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 54/94 reads (57%) | catalogued as COSV99902387; called by muse, mutect2, varscan2
- EPHA4 | c.2194T>C p.S732P | Missense Mutation (SNP) | VAF 86/571 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56035326; called by muse, mutect2, varscan2
- FCER1G | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 128/1005 reads (13%) | catalogued as rs752641092, COSV57154228, COSV99248145; called by muse, mutect2, varscan2
- HAUS8 | c.184A>T p.M62L | Missense Mutation (SNP) | VAF 25/497 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761305412, COSV99505550; called by muse, mutect2
- IL18RAP | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 21/471 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1298595373, COSV99962480; called by muse, mutect2
- INPP5J | c.1621G>A p.G541S (on ENST00000331075 / NM_001284285.2; = p.G173S on NM_001002837.2) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540212879, COSV100459871; called by muse, mutect2, varscan2
- KIR3DL3 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 209/835 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99400279; called by muse, mutect2, varscan2
- LARGE2 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201277259; called by muse, mutect2, varscan2
- LILRA2 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 150/548 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775165280, COSV99254033; called by muse, mutect2, varscan2
- NCAPD3 | c.3586A>G p.N1196D | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101592176; called by muse, mutect2, varscan2
- NEU4 | c.539G>A p.R180H (on ENST00000391969 / NM_001167602.3; = p.R192H on NM_080741.4) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1242690915, COSV100372227; called by muse, mutect2, varscan2
- NOD2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs375201229; called by muse, mutect2, varscan2
- PROKR1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs139618486; called by muse, mutect2, varscan2
- PTPRE | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99619186; called by muse, mutect2, varscan2
- RINT1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs770101080, COSV57557811; called by muse, mutect2, varscan2
- TMEM131L | c.4762A>C p.T1588P | Missense Mutation (SNP) | VAF 21/459 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99548246; called by muse, mutect2
- TMEM26 | c.862T>G p.F288V | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515875; called by muse, mutect2
- TNXB | c.4991G>A p.R1664H (on ENST00000647633; = p.R1417H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/595 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs777054871, COSV100925873; called by muse, mutect2, varscan2
- ZNF804A | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV100170520; called by muse, mutect2, varscan2
- AURKC | c.299_300del p.H100Pfs*8 (on ENST00000302804 / NM_001015878.2; = p.H66Pfs*8 on NM_003160.3) | Frame Shift Del (DEL) | VAF 91/547 reads (17%) | called by pindel, varscan2
- HSP90B1 | c.299del p.F100Sfs*2 | Frame Shift Del (DEL) | VAF 126/586 reads (22%) | called by mutect2, pindel, varscan2
- STYXL2 | c.-5_4del | Translation Start Site (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel
- TP53 | c.806_807del p.S269Ifs*2 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel
- ANK1 | c.2055T>C p.D685= | Silent (SNP) | VAF 69/282 reads (24%) | catalogued as COSV99227127; called by muse, mutect2, varscan2
- CMSS1 | c.183G>A p.K61= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV101375661; called by muse, mutect2, varscan2
- DYNC2H1 | c.2352A>G p.G784= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as COSV100519934; called by muse, mutect2, varscan2
- IFITM3 | c.294C>A p.A98= | Silent (SNP) | VAF 60/304 reads (20%) | catalogued as rs1389421335, COSV100068336; called by muse, mutect2, varscan2
- NIBAN2 | c.1056C>G p.V352= | Silent (SNP) | VAF 107/562 reads (19%) | catalogued as COSV100964979; called by muse, mutect2, varscan2
- PODXL | c.117G>A p.T39= | Silent (SNP) | VAF 57/303 reads (19%) | catalogued as rs768021099, COSV59869050; called by muse, mutect2, varscan2
- REV1 | c.2286T>G p.P762= | Silent (SNP) | VAF 113/550 reads (21%) | catalogued as COSV99301587; called by muse, mutect2, varscan2
- SLC32A1 | c.222C>T p.G74= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as COSV99462737; called by muse, mutect2, varscan2
- SNTG2 | c.882C>T p.S294= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs375891281; called by muse, mutect2, varscan2
- USP35 | c.1530G>A p.T510= | Silent (SNP) | VAF 149/616 reads (24%) | catalogued as rs555148298, COSV71572583; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.546A>G | RNA (SNP) | VAF 109/762 reads (14%) | called by muse, mutect2, varscan2
- SLC4A3 | c.612-50A>G | Intron (SNP) | VAF 22/203 reads (11%) | catalogued as COSV99813345; called by muse, mutect2, varscan2
